Somatic mutation profile of tumor specimen 0DLZOM from CCDI case PBCABT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Choroid plexus papilloma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.1 years (2,225 days).
Specimen 0DLZOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cd64ef5-3c8c-4987-8387-b9f22521cb7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLZOF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc1b1e41-7448-44dd-b667-e24b89c1ef99

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RADIL | c.2809G>A p.G937R | Missense Mutation (SNP) | VAF 88/619 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs769841031; called by muse, mutect2, varscan2
- TAAR9 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as COSV71512191; called by muse, mutect2, varscan2
- SNX32 | c.375-7C>G | Splice Region (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
